MMRF case MMRF_2220 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2a92bb6a-c860-4770-a20b-0738b94997d2

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 56.9 years (20,784 days); ISS stage: II; Days to last known disease status: 827 days (2.3 years); Days to last follow up: 827 days (2.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 4.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 99.1 mg/dL; Immunoglobulin G 51.4 g/L; Beta 2 Microglobulin 1.9 µg/mL; Hemoglobin 7.87 mmol/L; Leukocytes 5.45 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 31 g/L; Total Protein 9.9 g/dL; Glucose 5.12 mmol/L.
- Day 85 (ECOG 1): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.883 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.965 mg/dL; Immunoglobulin G 7.89 g/L; Hemoglobin 8.06 mmol/L; Leukocytes 3.89 ×10⁹/L; Absolute Neutrophil 2.68 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 4.13 mmol/L.
- Day 172 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.616 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.748 mg/dL; Immunoglobulin G 6.85 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 6.15 ×10⁹/L; Absolute Neutrophil 4.79 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 5.61 mmol/L.
- Day 281 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.985 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.892 mg/dL; Hemoglobin 8.06 mmol/L; Leukocytes 2.81 ×10⁹/L; Absolute Neutrophil 1.63 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 6.22 mmol/L.
- Day 365 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Hemoglobin 8.37 mmol/L; Leukocytes 4.46 ×10⁹/L; Absolute Neutrophil 2.89 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 5.5 mmol/L.
- Day 449 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.41 mg/dL; Hemoglobin 8.56 mmol/L; Leukocytes 3.49 ×10⁹/L; Absolute Neutrophil 1.94 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 4.62 mmol/L.
- Day 533 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Hemoglobin 8.37 mmol/L; Leukocytes 3.71 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 4.4 mmol/L.
- Day 645 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Hemoglobin 8.62 mmol/L; Leukocytes 3.43 ×10⁹/L; Absolute Neutrophil 2.04 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 5.06 mmol/L.
- Day 729 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Hemoglobin 8.49 mmol/L; Leukocytes 3.61 ×10⁹/L; Absolute Neutrophil 2.25 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 5.06 mmol/L.
- Day 827 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.22 mg/dL; Immunoglobulin G 9.18 g/L; Immunoglobulin A 0.86 g/L; Immunoglobulin M 0.69 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 3.17 ×10⁹/L; Absolute Neutrophil 1.77 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 6 mmol/L.

Other clinical attributes
- Day 1: Weight: 73 kg; Height: 172 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2220_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2220_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
